CPTAC case C3L-00102 — Pancreas — Ductal and Lobular Neoplasms (CPTAC-3)
Open-access clinical record from the NCI Genomic Data Commons (Data Release 46.0 - August 10, 2026), part of the Clinical Proteomic Tumor Analysis Consortium (CPTAC). Disease type: Ductal and Lobular Neoplasms; Primary site: Pancreas. Index date (day 0 for every day count below): diagnosis.
https://portal.gdc.cancer.gov/cases/adeb86f4-17ca-4ab1-b5aa-30ea0f5bdf56

Demographics
Sex at birth: male; Race: white; Ethnicity: not hispanic or latino; Year of birth: 1973; Vital status: Dead; Days to death: 249 days; Year of death: 2017; Cause of death: Cancer Related; Country of birth: United States.

Diagnoses (1)
1. Infiltrating duct carcinoma, NOS: ICD-O-3 morphology code: 8500/3; Tissue or organ of origin: Pancreas, NOS; Site of resection or biopsy: Head of pancreas; Age at diagnosis: 42.8 years (15,616 days); Year of diagnosis: 2016; AJCC staging edition: 7th; AJCC clinical M: M0; AJCC pathologic T: T3; AJCC pathologic N: N1; AJCC pathologic M: MX; AJCC pathologic stage: Stage IIB; Tumor grade: G3; Residual disease: R0; Last known disease status: With tumor; Days to last known disease status: 249 days; Progression or recurrence: yes; Days to last follow up: 249 days; Tumor focality: Unifocal.
   Pathology details: Greatest tumor dimension: 3 cm; Lymph node involvement: Positive; Lymph nodes positive: 5; Lymph nodes tested: 6; Lymphatic invasion present: Yes; Margin status: Involved; Perineural invasion present: Yes; Vascular invasion present: Yes.
   Chemotherapy — whether it was given is not recorded by GDC; Treatment outcome: Persistent Disease.

Follow-up (1 entry)
- Days to follow up: 249 days; Disease response: Progressive Disease; Progression or recurrence: Yes; Days to recurrence: 172 days.

Other clinical attributes
- Weight: 90 kg; Height: 182.8 cm; BMI: 26.93; Comorbidities: Hypertension.

Exposures
- Tobacco smoking status: Lifelong Non-Smoker.

Biospecimens (4 samples; slide percentages are pathologist estimates recorded by GDC per slide)
- Sample C3L-00102-01: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Biospecimen anatomic site: Pancreas; Preservation method: Snap Frozen; Freezing method: LN2; Days to sample procurement: 0 days; Initial weight: 566 mg; Time between excision and freezing: 30 minutes; Method of sample procurement: Tumor Resection; Diagnosis pathologically confirmed: Yes.
  Slide C3L-00102-21: Section location: Head; Percent tumor nuclei: 20; Percent necrosis: 0.
- Sample C3L-00102-02: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Preservation method: Snap Frozen; Freezing method: LN2; Initial weight: 424 mg.
- Sample C3L-00102-06: Sample type: Solid Tissue Normal; Tissue type: Normal; Specimen type: Solid Tissue; Biospecimen anatomic site: Pancreas; Preservation method: Snap Frozen; Freezing method: LN2; Days to sample procurement: 0 days; Initial weight: 534 mg; Time between excision and freezing: 30 minutes; Method of sample procurement: Surgical Resection; Diagnosis pathologically confirmed: Yes.
- Sample C3L-00102-31: Sample type: Blood Derived Normal; Tissue type: Normal; Specimen type: Peripheral Blood Components NOS; Biospecimen anatomic site: Blood; Preservation method: Frozen; Freezing method: -20 (unit not recorded by GDC); Days to sample procurement: 0 days; Method of sample procurement: Blood Draw.
